Gene-level copy-number profile of tumor specimen TCGA-29-2432-01A from TCGA case TCGA-29-2432, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.9 years (22,605 days).
Specimen TCGA-29-2432-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7092999f-069f-439e-a1fb-dcfaff2b8292.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-2432-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/87b958ac-a3c2-446c-adbd-689ebd0f2f1c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,197; copy number 2: 10,566; copy number 3: 20,985; copy number 4: 9,036; copy number 5: 9,099; copy number 6: 7,318; copy number 7: 705; copy number 8: 548; copy number 9: 175; copy number 10: 13; copy number 11: 171.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-2432-01A-01D-1043-01): tumor purity 0.64, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:47,593,208–47,593,440, 1 gene: AC004486.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,612 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–8,755,159, 181 genes, copy number 7 (broad region; genes not listed).
- chr5:12,574,830–13,944,543, 10 genes, copy number 7 (within-gene range 5–7): LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1.
- chr5:18,886,622–26,399,819, 72 genes, copy number 7 (broad region; genes not listed).
- chr6:67,888,977–67,998,751, 1 gene, copy number 8 (within-gene range 2–8): AL713998.4.
- chr6:68,040,290–68,576,191, 5 genes, copy number 8 (within-gene range 6–8): AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2.
- chr8:98,782,055–106,272,902, 159 genes, copy number 7 (broad region; genes not listed).
- chr8:123,178,960–123,210,079, 1 gene, copy number 7 (within-gene range 5–7): FAM83A.
- chr8:123,192,875–145,066,685, 422 genes, copy number 7–8 (broad region; genes not listed).
- chr12:20,810,702–21,090,245, 2 genes, copy number 10 (within-gene range 4–10): SLCO1B3, SLCO1B3-SLCO1B7.
- chr12:20,962,768–24,562,544, 43 genes, copy number 8–10 (within-gene range 6–10): SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1.
- chr18:67,506,587–80,247,514, 203 genes, copy number 7 (broad region; genes not listed).
- chr19:22,974,883–40,094,406, 513 genes, copy number 8–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
